Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A39Y, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A39Y-01A (Primary Tumor).

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Liver (segments 4A and V thru VIII - 1125 grams, 21 x 16 x 8 cm) and gallbladder (7.7 x 3.7 x 2.1 cm). A1, A2, B1, B2, B3

DIAGNOSIS:

Liver, segments 4A and V thru VIII, hepatectomy: Grade 3 (of 4) hepatocellular carcinoma forming a mass, 10.8 x 10 x 8 cm. The tumor involves the capsule. The surgical margin is free of tumor by 0.3 cm. A 0.6 cm hemangioma is present 0.3 cm from the tumor.

Gallbladder, cholecystectomy: Chronic cholecystitis with multiple (12) cholesterol polyps ranging in size from 0.1 to 0.4 cm in greatest dimension. No stones are identified.

ICD-0-3

carcinoma, hepatocellular, NOS 8170/3

Site Liver, C22.0 *hw* 9/22/11

Source: NCI Genomic Data Commons file b9c6213f-43ec-4531-8c8f-c11d27743928 (TCGA-DD-A39Y.2674265B-6B9D-49B3-9BD2-DF4E77AD4B26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).